Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6898, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6898-01A (Primary Tumor).

Department of Cancer Pathology

Date

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Partial organ resection – sigmoid colon.**

Unit in charge:

Physician in charge:

Material collected on:

Material received

Expected time of examination:

Clinical diagnosis:

Examination performed on:

Macroscopic description:

A 17 cm length of the large intestine with a fragment of the mesentery sized 19 x 6 x 1.5 cm. A cauliflower-shaped tumour sized 4.3 x 0.6 found in the mucosa. The lesion surrounds 100% of the intestine circumference and narrows its lumen, is located 7 cm 7 cm away from the other one. The lesion macroscopically infiltrates the intestinal wall.

Minimum side margin is 2.3 cm.

Microscopic description:

Adenocarcinoma tubulare (G2). Infiltratio carcinomatosa tunicae muscularis priopriae.

Excision lines clear of neoplastic infiltration.

Lymphonodulitis reactiva lymphonodorum (NO VIII).

Histopathology diagnosis:

Adenocarcinoma tubulare coli. Tubular adenocarcinoma of the colon.

(G1, Dukes A, Astler - Coller BI, pT2, pNO).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file fbb9750c-09ea-41e0-89b8-476437202283 (TCGA-D5-6898.DCE0850F-677E-4B31-9D4B-D92D1BFBB41A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).